CPTAC case C3L-02958 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/457097a8-e85b-453a-903d-7d992e70c1c8

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1943; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 74.3 years (27,124 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA1; Tumor grade: G1; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,741 days (4.8 years); Progression or recurrence: no; Days to last follow up: 1,741 days (4.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 0.9 cm (a second GDC size field records 3.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 11; Margin status: Uninvolved.

Follow-up (6 entries)
- Days to follow up: 467 days (1.3 years); Disease response: Tumor Free.
- Days to follow up: 685 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,044 days (2.9 years); Disease response: Complete Response.
- Days to follow up: 1,044 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,432 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,741 days (4.8 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 113.4 kg; Height: 185.42 cm; BMI: 32.98; FEV1/FVC before bronchodilator (%): 76; FEV1 after bronchodilator (% of reference): 76; FEV1 before bronchodilator (% of reference): 71.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 3; Cigarettes per day: 2; Tobacco smoking onset year: 1966; Tobacco smoking quit year: 1996; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 30.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02958-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 254 mg; Time between excision and freezing: 32 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02958-21: Section location: Right Upper Lobe; Percent tumor nuclei: 65; Percent necrosis: 0.
- Sample C3L-02958-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 262 mg; Time between excision and freezing: 32 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02958-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
